Somatic mutation profile of tumor specimen 0DVDUF from CCDI case PBCMSH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,331 days).
Specimen 0DVDUF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34588ca7-bd71-4e9c-8e5b-3698b92e3844.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDUZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331080ee-9e0c-476c-b910-1dd549804c90

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 2, Intron 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- HOXA2 | c.489_493del p.H163Qfs*20 | Frame Shift Del (DEL) | VAF 90/422 reads (21%) | called by pindel, varscan2
- MAPK6 | c.2131_2137del p.Q711Tfs*5 | Frame Shift Del (DEL) | VAF 37/201 reads (18%) | called by mutect2, pindel, varscan2
- BPTF | c.4467G>A p.Q1489= | Silent (SNP) | VAF 46/476 reads (10%) | catalogued as rs768855910; called by muse, mutect2, varscan2
- ATP6V0B | c.117-74del | Intron (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
